Surgical pathology report (de-identified scan), TCGA case TCGA-39-5040, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site MSKCC, specimen TCGA-39-5040-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Thoracic
Account: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
LUL lesion.

Specimens Submitted:

- 1: SP: Biopsy left upper lobe lung mass
- 2: SP: Level eleven lymph nodes
- 3: SP: Left upper lobe of lung
- 4: SP: Level seven lymph nodes
- 5: SP: AP window lymph nodes

DIAGNOSIS:

- 1) LUNG, LEFT UPPER LOBE; BIOPSY:
- NON-SMALL CELL CARCINOMA.
- 2) LYMPH NODE, LEVEL XI; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 3) LUNG, LEFT UPPER LOBE; LOBECTOMY:
- SQUAMOUS CELL CARCINOMA, WITH FOCAL PSEUDOVASCULAR CHANGES, OF LEFT UPPER LOBE, POORLY DIFFERENTIATED.
- THE TUMOR MEASURES 3.4 X 3.0 X 2.3.
- EXTENSIVE VASCULAR INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE PLEURA IS FREE OF TUMOR.
- NO IN SITU CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC LUNG SHOWS THE FOLLOWING ABNORMALITY(IES): EMPHYSEMATOUS CHANGES, RESPIRATORY BRONCHIOLITIS, RARE SMALL NON-NECROTIZING INTRAPULMONARY GRANULOMAS.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): PERIBRONCHIAL: 4/6.
- EXTRANODAL EXTENSION IS PRESENT.- METASTATIC CARCINOMA IS ALSO IDENTIFIED IN AN INTRAPULMONARY LYMPH NODE, WHICH IS MORE THAN 3 CM FROM THE MAIN TUMOR.

NOTE: IMMUNOSTAINS SHOW THAT THE TUMOR CELLS ARE POSITIVE FOR CK7 AND 34BE12, FOCALLY POSITIVE FOR CK20 AND 4A4, WHILE NEGATIVE FOR TTF-1, PE-10, THYROGLOBULIN AND CD31. THIS IMMUNOPROFILE SUPPORTS THE DIAGNOSIS OF

** Continued on next page **

[page 2 of 4]
[REDACTED]

----- Page 2 of 4 -----
SQUAMOUS CELL CARCINOMA. THE SPECIAL STAINS FOR AFB AND FUNGI ARE NEGATIVE.

- 4) LYMPH NODES, LEVEL VII; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODE, AP WINDOW; BIOPSY:
- METASTATIC CARCINOMA INVOLVING ONE OUT OF ONE LYMPH NODE (1/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result	Special Stain	Comment
	MUCIN	
	GMS	
	PATE	
	RECUT	

Gross Description:

[REDACTED]

1). The specimen is received fresh for frozen section consultation labeled "biopsy, left upper lung lobe mass" and consists of a 0.9 x 0.5 x 0.3 cm aggregate of red-tan soft tissue fragments, which are entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

[REDACTED]

2). The specimen is received fresh labeled "level 11 lymph nodes" and consists of multiple fragments of red-tan soft tissue measuring 1.5 x 1.0 x 0.4 cm in aggregate, which are entirely submitted for frozen section consultation.

Summary of sections:
FSC-frozen section control

[REDACTED]

3). The specimen is received in a fresh state for intraoperative consultation, labeled as "left upper lobe of lung", and consists of the left lung upper lobe lobectomy specimen measuring 15 x 12 x 4.2 cm, weighing 244 g. Sectioning reveals a well-circumscribed gray firm nodule measuring 3.4 x 3.0 x 2.3 cm in the lateral aspect of the specimen at 3 cm from the bronchial resection margin. The overlying pleura (inked) is grossly

** Continued on next page **

[page 3 of 4]
----- Page 3 of 4
uninvolved. The proximal portion of the tumor encases bronchial branches. Background pulmonary parenchyma shows diffuse emphysematous changes. Multiple peribronchial lymph nodes are identified. The specimen is photographed. TPS is taken. Representative sections are submitted.

Summary of sections:

FSC -- frozen section control (bronchial margin)
VM -- vascular margin
LN -- peribronchial lymph nodes
T -- tumor
RC -- background lung parenchyma adjacent to the tumor
RA -- background lung parenchyma away from the tumor

4). The specimen is received in formalin and is labeled "level 7 lymph nodes" consists of a pink-tan lymph node with focal anthracosis which measures 1.2 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

U-undesignated

5). The specimen is received in formalin and is labeled "AP window lymph nodes" and consists of a pink-tan lymph node which measures 1.5 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Biopsy left upper lobe lung mass

Block	Sect.	Site	PCs
1		fsc	1

Part 2: SP: Level eleven lymph nodes

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Left upper lobe of lung

Block	Sect.	Site	PCs
1		fsc	1
1		ln	1
2		ra	2
2		rc	2

** Continued on next page **

[page 4 of 4]
7 t 7
1 vm 1

Part 4: SP: Level seven lymph nodes

Block Sect. Site PCs
1 u 1

Part 5: SP: AP window lymph nodes

Block Sect. Site PCs
1 u 1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: BIOPSY LEFT UPPER LOBE LUNG
MASS (PS) NON-SMALL CELL CARCINOMA WITH PLEOMORPHIC FEATURES.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: SP: LEVEL ELEVEN LYMPH NODES
BENIGN.
PERMANENT DIAGNOSIS: SAME.

3) FROZEN SECTION DIAGNOSIS: SP: LEFT UPPER LOBE OF LUNG
BRONCHIAL MARGIN BENIGN.
PERMANENT DIAGNOSIS: SAME.

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: SP: BIOPSY LEFT UPPER LOBE LUNG
MASS NON-SMALL CELL CARCINOMA WITH PLEOMORPHIC FEATURES.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: SP: LEVEL ELEVEN LYMPH NODES
BENIGN.
PERMANENT DIAGNOSIS: SAME.

3) FROZEN SECTION DIAGNOSIS: SP: LEFT UPPER LOBE OF LUNG
BRONCHIAL MARGIN BENIGN.
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Source: NCI Genomic Data Commons file 6466ac3f-c392-4601-873b-d4c10a7e0e11 (TCGA-39-5040.6BEF6712-0D27-4032-9F72-3C9F13901223.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).